Gene-level copy-number profile of tumor specimen TCGA-VQ-A91V-01A from TCGA case TCGA-VQ-A91V, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 58.9 years (21,505 days).
Specimen TCGA-VQ-A91V-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.8aeac933-bd63-4a24-a482-10747da0ef26.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VQ-A91V-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/05ad96d2-0e9b-471a-af65-899d93d46147

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 20; copy number 1: 16,577; copy number 2: 37,656; copy number 3: 4,731; copy number 4: 690; copy number 5: 94; copy number 6: 17; copy number 19: 8; copy number 24: 1; copy number 27: 4; copy number 37: 22.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VQ-A91V-01A-11D-A40Z-01): tumor purity 0.86, ploidy 1.85, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 20 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,616,822–60,618,079, 2 genes: AC104164.2, MIR548BB.
- chr5:60,021,249–60,033,020, 1 gene: AC034234.1.
- chr9:9,090,898–9,803,784, 3 genes: RPS26P3, RN7SL5P, AL513422.1.
- chr12:18,080,869–18,739,188, 9 genes: RERGL, PIK3C2G, NDFIP1P1, AC092851.1, ZKSCAN7P1, PLCZ1, PSMC1P9, AC087242.1, CAPZA3.
- chr20:14,757,563–15,022,958, 5 genes: RPS10P2, MACROD2-AS1, AL138808.1, RNU6-1159P, RNU6-115P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 146 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:19,089,151–21,419,594, 32 genes, copy number 5–6: RPL7P6, MEF2BNBP1, PLEKHA5, AC092828.1, RN7SL459P, RN7SL67P, AEBP2, PDCD5P1, AC091805.2, RNU6-254P, EEF1A1P4, AC091805.1, AC137561.1, RNU1-146P, AC024901.1, TCP1P3, LINC02398, AC126468.1, LINC02468, AC129102.1, PDE3A, UBE2L2, AC112777.1, SLCO1C1, SLCO1B3, SLCO1B3-SLCO1B7, AC011604.1, SLCO1B7, AC022335.1, SLCO1B1, SLCO1A2, IAPP.
- chr12:23,108,458–23,108,493, 1 gene, copy number 24: AC087258.1.
- chr12:24,810,024–25,959,765, 30 genes, copy number 19–37: BCAT1, AC023796.2, AC026310.2, AC026310.1, BRI3P2, C12orf77, IRAG2, CENPUP2, AC023510.1, AC023510.2, CFAP94, ETFRF1, KRAS, AC092794.1, AC092794.2, AC087239.1, RNU4-67P, AC092451.1, LMNTD1, AC092451.2, FAM133GP, TUBB4BP1, AC022367.1, RN7SKP262, AC019209.3, TDGP1, AC019209.2, MIR4302, AC019209.1, RASSF8-AS1.
- chr12:31,111,652–34,249,958, 83 genes, copy number 5–27 (within-gene range 3–27) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 14,156. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
